Somatic mutation profile of tumor specimen TCGA-IE-A4EK-01A (aliquot TCGA-IE-A4EK-01A-11D-A24N-09) from TCGA case TCGA-IE-A4EK, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 54.3 years (19,815 days).
Specimen TCGA-IE-A4EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8c64fa7-c623-4222-b7b2-af3d5da5e04d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IE-A4EK-10A (Blood Derived Normal), aliquot TCGA-IE-A4EK-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00da3290-177b-4b88-9de8-cac33e6c66b8

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 36/42 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781255, CM128490, COSV64289445, COSV64291964; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.1660del p.V554Cfs*19 | Frame Shift Del (DEL) | VAF 36/80 reads (45%) | catalogued as COSV66330457; called by mutect2, pindel, varscan2
- FAM184A | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as rs748356563, COSV58854590; called by muse, mutect2, varscan2
- LRRIQ3 | c.116A>T p.H39L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs768274902; called by muse, mutect2, varscan2
- MED12L | c.4587G>A p.M1529I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs771224499; called by muse, mutect2, varscan2
- SLC22A14 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1325108644; called by muse, mutect2
- TMPRSS4 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as rs1565434309; called by muse, mutect2, varscan2
- TUBA8 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.331); catalogued as COSV57812989; called by muse, mutect2, varscan2
- EFHC2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT tolerated (0.41); PolyPhen benign (0.347); called by muse, varscan2
- EZR | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR3C | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RB1CC1 | c.1293A>C p.L431F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS1 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- SCN9A | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SNAP47 | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2
- GDF3 | c.477C>T p.T159= | Silent (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- KIF18B | c.822G>T p.G274= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- OPTC | c.600A>G p.L200= | Silent (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1413T>A p.I471= (on ENST00000352766; = p.I392= on NM_181334.5) | Silent (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- SLC6A11 | c.882C>T p.S294= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs996788555, COSV54396591, COSV99594369; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2019A>G | Intron (SNP) | VAF 29/84 reads (35%) | catalogued as rs1324145873; called by muse, mutect2, varscan2
